Somatic mutation profile of tumor specimen TCGA-B3-A6W5-01A (aliquot TCGA-B3-A6W5-01A-12D-A33Q-10) from TCGA case TCGA-B3-A6W5, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 43.7 years (15,945 days).
Specimen TCGA-B3-A6W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8565623-ef1a-435d-b6a8-591f4df7123f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-A6W5-10A (Blood Derived Normal), aliquot TCGA-B3-A6W5-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d28a11d-16c1-4d6e-94cb-c040d5eee61e

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 21, Silent 7, Splice Site 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS1 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99536439; called by muse, mutect2, varscan2
- ARHGAP24 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs377269441; called by muse, mutect2, varscan2
- CD180 | c.1297C>A p.H433N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs756339556, COSV99842354; called by muse, mutect2, varscan2
- CDH20 | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99406330; called by muse, mutect2
- CEACAM3 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs782333184, COSV99705090; called by muse, mutect2, varscan2
- DDX5 | c.1375G>C p.V459L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs782549207, COSV56747903, COSV99858210; called by muse, mutect2, varscan2
- FN1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.542); catalogued as COSV100118008; called by muse, mutect2, varscan2
- KCTD7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.509); catalogued as rs776661654, COSV51876679, COSV99299270; called by muse, mutect2, varscan2
- KDM3B | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100070152; called by muse, mutect2, varscan2
- MEPCE | c.1306G>C p.V436L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99440223; called by muse, mutect2, varscan2
- METTL21C | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940124; called by muse, mutect2, varscan2
- MMS22L | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs1240541636, COSV99247585; called by muse, mutect2, varscan2
- NCOA2 | c.3603G>A p.Q1201= | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99145014; called by muse, mutect2
- NTRK3 | c.1469C>A p.T490K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV100447828, COSV58135762; called by muse, mutect2, varscan2
- PAXIP1 | c.1484A>T p.H495L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as COSV101250022; called by muse, mutect2, varscan2
- PHC2 | c.2463C>G p.I821M (on ENST00000257118 / NM_198040.2; = p.I286M on NM_004427.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99931319; called by muse, mutect2, varscan2
- PTPN22 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs1354700890, COSV100703854; called by muse, mutect2, varscan2
- PTPRF | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100741140; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100741422; called by muse, mutect2, varscan2
- SC5D | c.32A>T p.Y11F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1312339895, COSV99873192; called by muse, mutect2, varscan2
- SH3TC1 | c.3556G>C p.G1186R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99795251; called by muse, mutect2, varscan2
- SYCP1 | c.1425+1G>A p.X475_splice | Splice Site (SNP) | VAF 83/248 reads (33%) | catalogued as rs761048469, COSV101051139; called by muse, mutect2, varscan2
- TTYH3 | c.28T>C p.W10R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99350087; called by muse, mutect2, varscan2
- SNRNP200 | c.4165-17_4168del p.X1389_splice | Splice Site (DEL) | VAF 26/57 reads (46%) | called by mutect2, pindel, varscan2
- ZNF257 | c.1529_1533del p.T510Rfs*7 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- ZNF462 | c.6777_6778del p.Y2261Sfs*10 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- CELSR2 | c.3402G>A p.E1134= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV99604590; called by muse, mutect2, varscan2
- COL4A3 | c.4317A>C p.A1439= | Silent (SNP) | VAF 154/273 reads (56%) | catalogued as COSV101170505; called by muse, mutect2, varscan2
- KCNJ15 | c.36C>A p.P12= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs767629629, COSV100154359; called by muse, mutect2, varscan2
- KIAA0232 | c.4077C>T p.R1359= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs143854680, COSV100301039; called by muse, mutect2, varscan2
- OBSCN | c.7845A>G p.V2615= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99483139; called by muse, mutect2, varscan2
- PSMG1 | c.12G>A p.T4= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1311346473, COSV100313937; called by muse, mutect2, varscan2
- SREBF2 | c.1647C>T p.V549= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs781174022, COSV100761530; called by muse, mutect2, varscan2
